Gene-level copy-number profile of tumor specimen ALCH-B2MV-TTP1-A from ALCHEMIST case ALCH-B2MV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,637 days).
Specimen ALCH-B2MV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 544ec476-2eba-4411-bcd3-41b8fa8b3eb4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/928e65d2-e857-40e7-8126-5f0ec544e39f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 3,919; copy number 2: 49,332; copy number 3: 4,450; copy number 4: 481; copy number 5: 63; copy number 6: 30; copy number 7: 7; copy number 69: 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,249,777–1,251,334, 1 gene: AL162741.1.
- chr1:12,824,605–12,841,357, 2 genes: PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.
- chr1:12,892,896–12,922,660, 3 genes (within-gene range 0–1): PRAMEF10, PRAMEF7, RNU6-1072P.
- chr1:17,717,625–17,749,978, 1 gene (within-gene range 0–1): LINC02810.
- chr2:44,921,077–44,941,873, 10 genes (within-gene range 0–1): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1.
- chr2:236,165,236–236,168,386, 1 gene (within-gene range 0–1): GBX2.
- chr3:109,293,788–109,364,234, 4 genes: DPPA2, Metazoa_SRP, DPPA4, AC124945.1.
- chr4:4,844,188–4,850,827, 1 gene: LINC01396.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:1,887,332–1,900,493, 1 gene: CTD-2194D22.4.
- chr7:63,556,598–63,585,075, 2 genes: SLC29A4P2, TNRC18P2.
- chr7:64,100,305–64,150,721, 13 genes: GUSBP6, MTND4P2, MTND4LP2, MTND3P2, MTCO3P8, MTATP6P18, MTCO2P8, MTCO1P8, MTND2P4, MTND1P2, AC091685.1, AC091685.2, VN1R37P.
- chr7:98,794,718–98,794,824, 1 gene: RNU6-393P.
- chr7:131,753,746–131,754,252, 1 gene: NDUFB9P2.
- chr8:7,028,641–7,056,739, 3 genes: DEFA11P, DEFA7P, DEFA5.
- chr8:7,112,314–7,143,841, 3 genes: AF228730.2, RPS3AP30, SNRPCP6.
- chr8:9,453,698–9,457,418, 1 gene: AC021242.1.
- chr8:20,551,201–20,551,405, 1 gene: AC022559.1.
- chr8:23,702,451–23,706,598, 1 gene: NKX2-6.
- chr8:25,593,197–25,688,786, 1 gene: AC009623.1.
- chr8:33,580,210–33,600,023, 2 genes: RN7SL621P, DUSP26.
- chr10:123,574,227–123,697,399, 2 genes: AL357127.1, GPR26.
- chr12:53,962,308–53,974,956, 5 genes (within-gene range 0–1): HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6.
- chr12:126,438,837–126,472,790, 2 genes: LINC02347, FAM32EP.
- chr12:130,425,004–130,430,661, 1 gene (within-gene range 0–1): AC063926.3.
- chr13:18,609,132–18,609,702, 1 gene: LONRF2P2.
- chr13:19,152,567–19,181,824, 3 genes: SMPD4P2, AL139327.3, TUBA3C.
- chr13:20,433,778–20,433,846, 1 gene (within-gene range 0–1): MIR4499.
- chr13:26,905,362–26,905,861, 1 gene: FGFR1OP2P1.
- chr14:76,310,712–76,501,837, 1 gene (within-gene range 0–1): ESRRB.
- chr14:93,895,762–93,927,066, 2 genes (within-gene range 0–1): AL132642.2, FAM181A-AS1.
- chr15:85,958,717–85,958,971, 1 gene: AC104229.1.
- chr17:36,722,443–36,726,346, 1 gene: AC243830.1.
- chr17:46,243,606–46,245,044, 1 gene: MAPK8IP1P1.
- chr17:51,165,435–51,171,744, 1 gene (within-gene range 0–3): NME2.
- chr18:78,795,612–78,796,672, 1 gene: AC044873.1.
- chr19:29,001,670–29,015,160, 2 genes: RNA5SP470, LINC01532.
- chr19:30,553,956–30,558,058, 1 gene (within-gene range 0–1): AC011504.1.
- chr19:56,066,684–56,078,801, 1 gene: LINC01864.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 98 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,957,231–234,980,804, 3 genes, copy number 7: AL391832.1, AL391832.2, AL391832.3.
- chr2:201,071,433–201,176,687, 9 genes, copy number 5 (within-gene range 3–5): NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P.
- chr4:15,681,662–15,705,565, 2 genes, copy number 5 (within-gene range 2–5): FAM200B, AC114744.2.
- chr5:38,556,765–38,671,216, 1 gene, copy number 5 (within-gene range 3–5): LIFR-AS1.
- chr5:38,682,070–38,685,126, 1 gene, copy number 5: AC010425.1.
- chr5:43,039,081–43,043,170, 1 gene, copy number 5 (within-gene range 4–5): ANXA2R.
- chr5:50,662,859–50,846,519, 2 genes, copy number 5: AC112187.3, PARP8.
- chr5:55,424,854–55,534,969, 2 genes, copy number 5 (within-gene range 4–5): PLPP1, AC010480.1.
- chr5:55,935,095–55,995,022, 1 gene, copy number 6 (within-gene range 3–6): IL6ST.
- chr5:55,944,656–56,111,329, 4 genes, copy number 6 (within-gene range 4–6): AC016596.2, AC008892.1, FLJ31104, AC016596.1.
- chr5:56,451,627–56,505,072, 2 genes, copy number 5: LINC01948, RPL26P19.
- chr5:67,268,022–67,270,182, 1 gene, copy number 5: AC010420.1.
- chr5:67,463,809–67,475,592, 1 gene, copy number 5 (within-gene range 4–5): AC079467.1.
- chr5:159,157,409–159,248,796, 4 genes, copy number 7: RNF145, AC134043.2, LINC01932, AC134043.1.
- chr5:159,865,080–159,973,012, 2 genes, copy number 5 (within-gene range 4–5): ADRA1B, GAPDHP40.
- chr6:11,183,298–11,382,348, 2 genes, copy number 5 (within-gene range 4–5): NEDD9, AL022098.1.
- chr6:32,578,769–32,668,383, 4 genes, copy number 5–6: HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr7:16,888,621–16,888,885, 1 gene, copy number 6: AC098592.2.
- chr7:17,033,089–17,033,478, 1 gene, copy number 6: BRWD1P3.
- chr7:57,200,825–57,203,597, 1 gene, copy number 5: GUSBP12.
- chr7:130,791,264–131,110,161, 1 gene, copy number 5 (within-gene range 2–5): AC016831.6.
- chr7:130,938,963–131,110,176, 2 genes, copy number 5 (within-gene range 2–5): LINC-PINT, RNU6-1010P.
- chr8:143,816,344–143,832,861, 2 genes, copy number 5: PUF60, AC234917.3.
- chr10:3,833,950–3,834,728, 1 gene, copy number 5: LINC02639.
- chr11:127,204–207,428, 4 genes, copy number 5–6 (within-gene range 2–7): LINC01001, BET1L, SCGB1C1, ODF3.
- chr11:65,455,258–65,538,704, 9 genes, copy number 6 (within-gene range 4–6): AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.
- chr11:96,352,769–96,389,956, 1 gene, copy number 5: CCDC82.
- chr13:75,620,434–75,859,870, 1 gene, copy number 5 (within-gene range 3–6): LMO7.
- chr13:75,688,556–75,689,197, 1 gene, copy number 5 (within-gene range 3–6): FAM204CP.
- chr14:35,278,633–35,317,493, 1 gene, copy number 5 (within-gene range 4–5): PSMA6.
- chr14:36,213,200–36,320,637, 3 genes, copy number 6: AL162511.1, RN7SKP21, MBIP.
- chr14:36,371,165–36,405,274, 2 genes, copy number 6: DPPA3P2, RNU7-93P.
- chr16:11,741,910–11,828,845, 5 genes, copy number 6 (within-gene range 2–6): AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr16:69,187,129–69,309,052, 3 genes, copy number 5 (within-gene range 3–5): SNTB2, Y_RNA, AC026474.1.
- chr18:9,914,016–9,960,021, 2 genes, copy number 5: VAPA, RNA5SP450.
- chr19:1,248,553–1,279,244, 4 genes, copy number 5: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,407,569–1,435,687, 1 gene, copy number 5: DAZAP1.
- chr20:50,429,190–50,585,241, 6 genes, copy number 5: RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–69: LINC00319, LINC00313, AP001048.1.
- chr22:24,269,346–24,270,134, 1 gene, copy number 5: AP000354.1.

Autosomal genes at a single copy (total copy number 1): 3,919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
